Gene-level copy-number profile of tumor specimen ALCH-B2AR-TTP1-A from ALCHEMIST case ALCH-B2AR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.7 years (27,298 days).
Specimen ALCH-B2AR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3b9af0fd-6e2c-4782-b2ed-0cf7a09e8674.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/14edc4b6-7cc8-44f9-8632-b86305c99da4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 3,094; copy number 2: 55,611; copy number 3: 177; copy number 4: 8; copy number 5: 1; copy number 7: 4; copy number 8: 3; copy number 11: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,637,845–64,836,341, 6 genes, copy number 5–11: AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1.
- chr22:18,623,339–18,625,289, 1 gene, copy number 7: SUSD2P2.
- chr22:18,846,811–18,894,407, 4 genes, copy number 7–8 (within-gene range 7–20): AC008132.1, BCRP7, FAM230F, AC008103.1.
- chr22:18,936,411–18,947,741, 1 gene, copy number 8 (within-gene range 3–8): AC007326.5.

Autosomal genes at a single copy (total copy number 1): 287. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
